Somatic mutation profile of tumor specimen HCM-BROD-0210-C71-02A (aliquot HCM-BROD-0210-C71-02A-11D-A78T-36) from HCMI case HCM-BROD-0210-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.6 years (19,586 days).
Specimen HCM-BROD-0210-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8063506-9a52-4697-b72c-a861f5e6a0f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0210-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0210-C71-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6632489a-9da8-480d-8c0e-9db615477fc7

The open-access MAF lists 61 somatic variants for this specimen: 37 protein-altering or splice-affecting, 17 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 17, Intron 4, Nonsense Mutation 2, 5'UTR 2, Splice Region 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1166T>A p.L389* | Nonsense Mutation (SNP) | VAF 29/155 reads (19%) | catalogued as rs587778845, CM071074, COSV57298834, COSV99923545; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 114/728 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMPD1 | c.315-8G>A | Splice Region (SNP) | VAF 28/348 reads (8%) | catalogued as rs762655218, COSV62415799; ClinVar: likely benign; called by muse, mutect2
- ANKRD30B | c.4024C>T p.R1342C | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1432131805; called by muse, mutect2
- ARHGEF6 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 35/447 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.784); catalogued as rs1368379563; called by muse, mutect2
- CACNA1B | c.6758G>A p.R2253Q | Missense Mutation (SNP) | VAF 60/451 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1232097200, COSV53147809; called by muse, mutect2, varscan2
- CDR1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs538565518; called by muse, mutect2
- DCAF12L1 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 36/285 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV100948428, COSV64421531; called by muse, mutect2, varscan2
- DPT | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs148412326; called by muse, mutect2, varscan2
- DSG1 | c.1409A>G p.N470S | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs933463366; called by muse, mutect2, varscan2
- DZIP3 | c.3173G>A p.R1058Q | Missense Mutation (SNP) | VAF 44/306 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs138409858; called by muse, mutect2, varscan2
- GCNA | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 78/732 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as rs1292180999; called by muse, mutect2, varscan2
- IGKV2-24 | c.36G>A p.M12I | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs775559803; called by muse, mutect2
- INTS6L | c.1663G>C p.G555R | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66086465; called by muse, mutect2
- KRTAP12-2 | c.304T>C p.S102P | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as rs1173732058; called by muse, mutect2
- MYOM1 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 49/538 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1334526476; called by muse, mutect2
- NOX3 | c.1541G>A p.W514* | Nonsense Mutation (SNP) | VAF 40/342 reads (12%) | catalogued as rs749685924, COSV50150407; called by muse, mutect2, varscan2
- OR10G3 | c.14A>G p.N5S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs752631358; called by muse, mutect2
- PTEN | c.100G>C p.A34P | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100909680, COSV64293534, COSV64307061; called by muse, mutect2, varscan2
- SERPINB7 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs750323054, COSV60532739; called by muse, mutect2, varscan2
- TBX4 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs748931901; called by muse, mutect2, varscan2
- TPO | c.2689G>A p.G897R | Missense Mutation (SNP) | VAF 26/746 reads (3%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs569075835, COSV61109637; called by muse, mutect2
- AFF2 | c.2032C>G p.P678A | Missense Mutation (SNP) | VAF 36/326 reads (11%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- CLEC4F | c.1471C>T p.H491Y | Missense Mutation (SNP) | VAF 29/322 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- CMYA5 | c.776A>T p.Y259F | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- COL6A5 | c.3496T>A p.F1166I | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- DNAH8 | c.1837A>C p.K613Q | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- DNAH8 | c.3752A>T p.Y1251F | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- FAM160A1 | c.871T>A p.F291I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MDC1 | c.4999G>A p.D1667N | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.585); called by muse, mutect2
- MRPS28 | c.332A>G p.D111G | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MYPN | c.3637C>G p.P1213A | Missense Mutation (SNP) | VAF 19/490 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHGB1 | c.2372A>T p.D791V | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PDILT | c.1373A>G p.D458G | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SHANK2 | c.1921_1936+1del p.X641_splice | Splice Site (DEL) | VAF 27/195 reads (14%) | called by mutect2, pindel, varscan2
- TMPRSS15 | c.1186A>G p.T396A | Missense Mutation (SNP) | VAF 52/431 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, varscan2
- ZNF275 | c.430T>C p.F144L | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- DAG1 | c.600C>T p.T200= | Silent (SNP) | VAF 42/888 reads (5%) | called by muse, mutect2
- EBF1 | c.1335G>A p.V445= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- FBLN1 | c.792C>T p.D264= | Silent (SNP) | VAF 38/382 reads (10%) | catalogued as rs144704783; called by muse, mutect2, varscan2
- FNDC1 | c.2421G>A p.T807= | Silent (SNP) | VAF 16/214 reads (7%) | catalogued as rs1028491793, COSV51940488, COSV51944638; called by muse, mutect2
- LILRA4 | c.612C>T p.Y204= | Silent (SNP) | VAF 37/194 reads (19%) | catalogued as rs149766788, COSV52491834; called by muse, mutect2
- MCM3AP | c.2091C>T p.L697= | Silent (SNP) | VAF 76/627 reads (12%) | catalogued as rs371262030; called by muse, mutect2, varscan2
- MOSPD2 | c.15C>T p.H5= | Silent (SNP) | VAF 30/312 reads (10%) | catalogued as COSV60761167; called by muse, mutect2, varscan2
- MYPN | c.3636C>A p.I1212= | Silent (SNP) | VAF 18/476 reads (4%) | catalogued as COSV62735500; called by muse, mutect2
- PALLD | c.2010T>C p.D670= | Silent (SNP) | VAF 26/622 reads (4%) | called by muse, mutect2
- PCDHA5 | c.198G>A p.A66= | Silent (SNP) | VAF 97/700 reads (14%) | catalogued as rs782275396, COSV65357826; called by muse, mutect2, varscan2
- SLC16A5 | c.555C>T p.C185= | Silent (SNP) | VAF 46/311 reads (15%) | catalogued as rs770508660; called by muse, mutect2, varscan2
- SLC23A1 | c.1008C>T p.I336= | Silent (SNP) | VAF 42/335 reads (13%) | catalogued as rs373518978; called by muse, mutect2, varscan2
- STIM2 | c.1686C>G p.L562= | Silent (SNP) | VAF 50/379 reads (13%) | called by muse, mutect2, varscan2
- TSHZ3 | c.561G>A p.E187= | Silent (SNP) | VAF 49/316 reads (16%) | called by muse, varscan2
- UGT2B11 | c.1407C>A p.P469= | Silent (SNP) | VAF 61/438 reads (14%) | catalogued as rs1437515630; called by muse, mutect2, varscan2
- UGT2B17 | c.393A>G p.A131= | Silent (SNP) | VAF 34/267 reads (13%) | called by muse, mutect2, varscan2
- ZNF783 | c.684G>A p.P228= | Silent (SNP) | VAF 52/385 reads (14%) | catalogued as rs746987451, COSV65185145; called by muse, mutect2, varscan2
- ADGRF1 | c.612-1797G>T | Intron (SNP) | VAF 13/190 reads (7%) | called by muse, mutect2
- ARHGEF4 | chr2:130915617 G>T | 5'Flank (SNP) | VAF 38/333 reads (11%) | called by muse, mutect2, varscan2
- LIG3 | c.2796+255G>T | Intron (SNP) | VAF 13/307 reads (4%) | called by muse, mutect2
- MAML3 | c.468+18644G>A | Intron (SNP) | VAF 10/242 reads (4%) | catalogued as rs1347032672; called by muse, mutect2
- MAMLD1 | c.-22G>C | 5'UTR (SNP) | VAF 40/286 reads (14%) | catalogued as COSV99475676; called by muse, mutect2, varscan2
- MRPS24 | c.-2A>C | 5'UTR (SNP) | VAF 17/272 reads (6%) | called by muse, mutect2
- UGT1A6 | c.862-12079G>A | Intron (SNP) | VAF 51/370 reads (14%) | catalogued as rs767638744, COSV100529352; called by muse, mutect2, varscan2
